Gene-level copy-number profile of tumor specimen C3L-04085-01 (profiled together with C3L-04085-02, C3L-04085-04) from CPTAC case C3L-04085, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 79.3 years (28,971 days).
Specimen C3L-04085-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 06cd5606-4356-48b7-b7c9-5ea94e539d3e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04085-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/73a73cd9-56b2-48c0-b480-f07a7b28d808

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 2: 8,894; copy number 3: 11,386; copy number 4: 26,286; copy number 5: 10,270; copy number 6: 1,897; copy number 8: 10; copy number 19: 40; copy number 34: 2; copy number 74: 2; copy number 77: 8; copy number 78: 32; copy number 80: 1; copy number 82: 48; copy number 83: 1; copy number 97: 21; copy number 98: 2; copy number 100: 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:18,422,244–18,530,573, 7 genes: FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 158 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:47,914,142–48,426,201, 8 genes, copy number 77 (within-gene range 4–77): NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2.
- chr4:51,843,000–55,905,086, 80 genes, copy number 78–82 (broad region; genes not listed).
- chr11:68,612,899–70,075,469, 40 genes, copy number 19 (within-gene range 5–19): AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P.
- chr12:31,019,434–31,073,847, 1 gene, copy number 100 (within-gene range 6–100): DDX11-AS1.
- chr12:57,591,174–57,808,071, 21 genes, copy number 97 (within-gene range 6–97): PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM.
- chr12:106,774,621–106,889,316, 2 genes, copy number 98 (within-gene range 3–98): RIC8B, AC007695.1.
- chr12:110,846,769–110,907,535, 1 gene, copy number 80: CCDC63.
- chr12:111,686,053–111,757,107, 1 gene, copy number 83 (within-gene range 3–83): ACAD10.
- chr12:127,598,168–127,619,447, 2 genes, copy number 34: AC025252.1, Y_RNA.
- chr12:131,711,081–131,799,738, 2 genes, copy number 74: SFSWAP, AC117500.2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
